Somatic mutation profile of tumor specimen TCGA-CG-4305-01A (aliquot TCGA-CG-4305-01A-01D-1158-08) from TCGA case TCGA-CG-4305, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 69.3 years (25,295 days).
Specimen TCGA-CG-4305-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fd176b2-73f7-4f2c-88ac-a33cad7a9bc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4305-10A (Blood Derived Normal), aliquot TCGA-CG-4305-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c84864e9-cd01-4352-8131-b591ff0f1a1e

The open-access MAF lists 1,454 somatic variants for this specimen: 1,109 protein-altering or splice-affecting, 307 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 708, Silent 307, Frame Shift Del 280, Frame Shift Ins 46, Nonsense Mutation 41, Intron 17, Splice Site 15, Splice Region 8, RNA 8, In Frame Del 8, 3'UTR 6, 5'UTR 3.

Variants (750 of 1,454; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 13/94 reads (14%) | catalogued as rs376926391, CM082466, CM122251; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGXT | c.33del p.K12Rfs*34 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs180177201, CM056286; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BARD1 | c.623del p.K208Rfs*4 | Frame Shift Del (DEL) | VAF 23/129 reads (18%) | catalogued as rs587780033; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BVES | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 21/117 reads (18%) | catalogued as rs796206315, COSV58947369; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FAM161A | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 38/222 reads (17%) | catalogued as rs267606794, CM105647, COSV56765545; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLCN | c.1579C>T p.R527* | Nonsense Mutation (SNP) | VAF 57/318 reads (18%) | catalogued as rs879255683, CM051478, COSV53258809; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KCNQ3 | c.1599del p.K533Nfs*6 | Frame Shift Del (DEL) | VAF 27/195 reads (14%) | catalogued as rs762289015, COSV101196388; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- KMT2A | c.2318del p.P773Rfs*8 | Frame Shift Del (DEL) | VAF 42/255 reads (16%) | catalogued as rs782297546; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 26/150 reads (17%) | catalogued as rs763183959; ClinVar: pathogenic; called by pindel, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, pindel
- MPZ | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913590, CM960980, CM960981, COSV60668117; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 38/241 reads (16%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NIPBL | c.5335C>T p.R1779* | Nonsense Mutation (SNP) | VAF 16/83 reads (19%) | catalogued as rs587783971, COSV56949230; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 21/41 reads (51%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 20/101 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PPARG | c.556del p.S186Vfs*47 (on ENST00000287820 / NM_015869.5; = p.S156Vfs*47 on NM_005037.7) | Frame Shift Del (DEL) | VAF 17/99 reads (17%) | catalogued as rs587776687; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 24/123 reads (20%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- RASA1 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as rs137853218, CM081410, COSV57192495; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPART | c.696del p.F232Lfs*2 | Frame Shift Del (DEL) | VAF 21/143 reads (15%) | catalogued as rs770560051; ClinVar: pathogenic; called by mutect2, varscan2
- TREX1 | c.144del p.T49Pfs*16 (on ENST00000625293 / NM_033629.6; = p.T39Pfs*16 on NM_007248.5) | Frame Shift Del (DEL) | VAF 28/173 reads (16%) | catalogued as rs748914604; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TREX1 | c.397del p.L133Cfs*27 (on ENST00000625293 / NM_033629.6; = p.L123Cfs*27 on NM_007248.5) | Frame Shift Del (DEL) | VAF 11/101 reads (11%) | catalogued as rs78762691; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- A2M | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1259395599, COSV59385400; called by muse, mutect2, varscan2
- ABCC4 | c.3655del p.I1219Sfs*11 | Frame Shift Del (DEL) | VAF 34/186 reads (18%) | catalogued as rs756859429, COSV65316407; called by mutect2, varscan2
- ABCF3 | c.2034G>A p.W678* | Nonsense Mutation (SNP) | VAF 48/341 reads (14%) | catalogued as COSV53052038; called by muse, mutect2, varscan2
- ACAP2 | c.1330C>A p.L444I | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58751361; called by muse, mutect2, varscan2
- ACCSL | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs371000393, COSV66580564; called by muse, mutect2, varscan2
- ACO1 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 77/339 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1036093594, COSV59379264; called by muse, mutect2, varscan2
- ACO1 | c.2174C>T p.A725V | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59379287; called by muse, mutect2, varscan2
- ACTL9 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1420072536, COSV61005519; called by mutect2, varscan2
- ACVR1B | c.206G>A p.C69Y | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57776359; called by muse, mutect2
- ACVR1B | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1460557299, COSV57776372, COSV57780549; called by muse, mutect2
- ADAM11 | c.1757C>A p.S586Y | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV99567770; called by muse, mutect2, varscan2
- ADAMTS16 | c.2992-1G>A p.X998_splice | Splice Site (SNP) | VAF 12/96 reads (13%) | catalogued as COSV99942624; called by muse, mutect2, varscan2
- ADAMTS18 | c.2085del p.F695Lfs*7 | Frame Shift Del (DEL) | VAF 32/172 reads (19%) | catalogued as rs772504358, COSV51414270; called by mutect2, varscan2
- ADAMTS5 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.355); catalogued as COSV53178160; called by muse, mutect2, varscan2
- ADAP2 | c.805-1G>A p.X269_splice | Splice Site (SNP) | VAF 68/335 reads (20%) | catalogued as COSV58295688; called by muse, mutect2, varscan2
- ADCY5 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1323580093, COSV71901332; called by muse, mutect2
- ADGRA1 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776693044, COSV66924677; called by muse, mutect2, varscan2
- ADGRL3 | c.374A>C p.N125T (on ENST00000506720 / NM_001322402.2; = p.N57T on NM_015236.6) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72267982; called by muse, mutect2, varscan2
- ADORA1 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs2275349, COSV58809914; called by muse, mutect2, varscan2
- AGAP1 | c.2023A>G p.K675E (on ENST00000304032 / NM_001037131.3; = p.K622E on NM_014914.5) | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.94); PolyPhen benign (0.422); catalogued as COSV58323494; called by muse, mutect2, varscan2
- AGBL1 | c.2380C>T p.R794C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759191613, COSV66848829; called by muse, mutect2, varscan2
- AHDC1 | c.4650del p.V1551Cfs*57 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as COSV55939343; called by mutect2, pindel, varscan2
- AIG1 | c.490A>G p.T164A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs114392595, COSV51625210; called by muse, mutect2
- AK9 | c.5456C>T p.A1819V | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs372465779, COSV69850596; called by muse, mutect2
- ALDH16A1 | c.2090C>T p.A697V | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs539901155, COSV53193653; called by muse, mutect2, varscan2
- ALDH1L1 | c.1691T>A p.V564D | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV99857402; called by muse, mutect2, varscan2
- ALKBH7 | c.227C>T p.T76I | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as rs1555720793, COSV55532075; called by muse, mutect2, varscan2
- ALMS1 | c.3751C>T p.Q1251* | Nonsense Mutation (SNP) | VAF 29/205 reads (14%) | catalogued as rs778724795, CM156219, COSV52507960; called by muse, mutect2, varscan2
- ALMS1 | c.10190A>G p.E3397G | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV52507969; called by muse, mutect2, varscan2
- ALX4 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as rs1475499990, COSV61326030; called by muse, mutect2, varscan2
- AMHR2 | c.800del p.G267Vfs*25 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | catalogued as rs748387033; called by mutect2, pindel, varscan2
- AMY1A | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 54/860 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs755582791, COSV64410943; called by muse, mutect2
- AMY1B | c.1007A>G p.Y336C | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100375569; called by mutect2, varscan2
- AMZ2 | c.340T>G p.Y114D | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.734); catalogued as COSV63082769; called by muse, mutect2, varscan2
- ANAPC15 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 49/263 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV56191606; called by muse, mutect2, varscan2
- ANGPT2 | c.700del p.I234* | Frame Shift Del (DEL) | VAF 34/227 reads (15%) | catalogued as rs34047276; called by mutect2, varscan2
- ANGPTL6 | c.905G>T p.R302M | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53461978; called by muse, mutect2, varscan2
- ANK1 | c.5104G>A p.D1702N | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV55879221; called by muse, mutect2, varscan2
- ANK1 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.947); catalogued as rs1397520683, COSV55879232, COSV55885986; called by muse, mutect2
- ANK3 | c.11150A>C p.K3717T | Missense Mutation (SNP) | VAF 67/300 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55053771; called by muse, mutect2, varscan2
- ANKLE1 | c.1775G>A p.C592Y (on ENST00000394458; = p.C538Y on NM_152363.6) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66730815; called by muse, mutect2, varscan2
- ANKRD13B | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.223); catalogued as rs199786725, COSV67473712; called by muse, mutect2, varscan2
- ANO3 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.508); catalogued as rs187173978, COSV56788782; called by muse, mutect2, varscan2
- ANOS1 | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as rs201842998, COSV52918569, COSV52928370; called by muse, mutect2, varscan2
- ANXA1 | c.923T>C p.M308T | Missense Mutation (SNP) | VAF 75/314 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as rs766591114, COSV57411048; called by muse, mutect2, varscan2
- ANXA13 | c.119T>C p.I40T | Missense Mutation (SNP) | VAF 42/326 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV51622731; called by muse, mutect2, varscan2
- AP1G2 | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 20/92 reads (22%) | catalogued as rs199932071, COSV55339571; called by muse, mutect2, varscan2
- AP3M2 | c.227del p.P76Lfs*26 | Frame Shift Del (DEL) | VAF 26/191 reads (14%) | catalogued as rs759247606, COSV51528744; called by mutect2, pindel, varscan2
- AP4M1 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.376); catalogued as rs867649912, COSV57995743; called by muse, mutect2, varscan2
- APMAP | c.945del p.Y316Tfs*29 | Frame Shift Del (DEL) | VAF 10/102 reads (10%) | catalogued as rs777444320; called by mutect2, pindel
- APOA5 | c.421G>C p.A141P | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.93); catalogued as COSV57062965; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | catalogued as rs749401724; called by mutect2, varscan2
- AQR | c.3260G>A p.R1087Q | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1475151589, COSV50032266, COSV99334099; called by muse, mutect2, varscan2
- ARAP2 | c.4545G>A p.W1515* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV58285604; called by muse, mutect2, varscan2
- ARHGAP39 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs1235988824, COSV52769171; called by muse, mutect2, varscan2
- ARHGAP5 | c.2812G>T p.V938F | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61535061; called by muse, mutect2, varscan2
- ARHGAP6 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.84); catalogued as rs766331432, COSV61625847; called by muse, mutect2, varscan2
- ARHGEF10 | c.2606G>A p.G869E (on ENST00000398564; = p.G844E on NM_014629.4) | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV50646482; called by muse, mutect2, varscan2
- ARHGEF10L | c.1678C>A p.R560S | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51429038, COSV51431042; called by muse, mutect2, varscan2
- ARHGEF4 | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs542532426, COSV58124930; called by muse, mutect2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 22/149 reads (15%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID5B | c.1489del p.I497* | Frame Shift Del (DEL) | VAF 20/111 reads (18%) | catalogued as rs201178069; called by mutect2, pindel, varscan2
- ARRDC2 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs753164311, COSV55844170; called by muse, mutect2, varscan2
- ARRDC2 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1322624401, COSV55844183; called by muse, mutect2, varscan2
- ARVCF | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs376589668; called by mutect2, varscan2
- ASAP1 | c.1149dup p.S384Ifs*3 | Frame Shift Ins (INS) | VAF 30/246 reads (12%) | catalogued as rs1486733426; called by mutect2, pindel, varscan2
- ASB3 | c.1018T>C p.Y340H | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.081); catalogued as COSV55075208; called by muse, mutect2, varscan2
- ASB9 | c.65T>G p.I22S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV66851608; called by muse, mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 34/193 reads (18%) | catalogued as rs761154268; called by mutect2, varscan2
- ASPSCR1 | c.755del p.L252Rfs*11 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs754464527, COSV60727771; called by mutect2, varscan2
- ASTE1 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV53908447; called by muse, mutect2, varscan2
- ASXL2 | c.2765C>T p.A922V | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV55457494; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 42/258 reads (16%) | catalogued as rs746676748; called by mutect2, varscan2
- ATAD2B | c.920del p.K307Rfs*57 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | catalogued as rs1558707706; called by mutect2, pindel
- ATAD5 | c.3579T>A p.F1193L | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1021870588, COSV58973543, COSV58976914; called by muse, varscan2
- ATP1A4 | c.3041T>G p.L1014R | Missense Mutation (SNP) | VAF 64/335 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.673); catalogued as COSV63624055; called by muse, mutect2, varscan2
- ATP6V1G2 | c.156G>T p.E52D | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.346); catalogued as COSV58214303; called by muse, mutect2, varscan2
- ATXN3 | c.668A>G p.D223G | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV61494824; called by muse, mutect2, varscan2
- B3GALNT2 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as rs775573521, COSV58356200; called by muse, varscan2
- BATF | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.267); catalogued as rs868223395, COSV54375667; called by muse, varscan2
- BCAN | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753351484, COSV61256276; called by muse, mutect2, varscan2
- BCR | c.3316G>A p.D1106N | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.752); catalogued as rs879255379, COSV59926054; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BEX3 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.579); catalogued as COSV100244374, COSV55420986; called by muse, mutect2, varscan2
- BIN2 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs969445320, COSV57204967; called by muse, mutect2, varscan2
- BLNK | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 50/285 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs781845656, COSV56410328; called by muse, mutect2, varscan2
- BMP5 | c.1358G>T p.C453F | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63702618; called by muse, mutect2, varscan2
- BMPR2 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770128128, COSV65808758; called by muse, mutect2, varscan2
- BRCA2 | c.7054C>T p.P2352S | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV66452269; called by muse, mutect2, varscan2
- BRD3 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.5); catalogued as COSV100325476; called by muse, mutect2, varscan2
- BRPF1 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546077809, COSV57404336; called by muse, mutect2, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- BTBD7 | c.173del p.K58Rfs*44 | Frame Shift Del (DEL) | VAF 42/265 reads (16%) | catalogued as rs752512017; called by mutect2, varscan2
- BTN2A1 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.304); catalogued as rs369006610; called by muse, mutect2, varscan2
- C14orf180 | c.135del p.S46Pfs*3 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs761345073; called by pindel, varscan2
- C17orf80 | c.1567G>A p.G523R | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764164900, COSV52145869; called by muse, mutect2, varscan2
- C1QTNF12 | c.253G>C p.G85R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV57802540; called by muse, mutect2, varscan2
- C1QTNF7 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs776483061, COSV54850388; called by muse, mutect2, varscan2
- C1orf122 | c.268del p.Q90Sfs*42 | Frame Shift Del (DEL) | VAF 27/170 reads (16%) | catalogued as rs747134922; called by mutect2, pindel, varscan2
- C8orf33 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); catalogued as rs763426794, COSV58895518; called by muse, mutect2, varscan2
- C8orf58 | c.583C>A p.L195M | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51515017; called by muse, mutect2, varscan2
- CACNA1E | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV62390499; called by muse, mutect2, varscan2
- CACNA1E | c.6596C>A p.A2199D (on ENST00000367573 / NM_001205293.3; = p.A2156D on NM_000721.4) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV62390529; called by muse, mutect2, varscan2
- CACNA2D1 | c.2380G>C p.V794L (on ENST00000356253 / NM_001366867.1; = p.V782L on NM_000722.4) | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV62377501, COSV62382685; called by muse, varscan2
- CACNA2D1 | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 62/468 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV62377507; called by muse, mutect2, varscan2
- CACNB2 | c.1531C>T p.R511C (on ENST00000324631 / NM_201596.3; = p.R456C on NM_000724.4) | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as rs764111314, COSV56620175; called by muse, mutect2, varscan2
- CADM1 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV59008254; called by muse, mutect2, varscan2
- CALCRL | c.755T>C p.L252S | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66474529; called by muse, mutect2, varscan2
- CANX | c.1305del p.F435Lfs*12 | Frame Shift Del (DEL) | VAF 38/154 reads (25%) | catalogued as rs760711956; called by mutect2, varscan2
- CAPN15 | c.615del p.E207Kfs*80 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as COSV99562455; called by mutect2, varscan2
- CAPN7 | c.2105G>A p.G702E | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53777816; called by muse, mutect2, varscan2
- CAPS2 | c.1104T>C p.G368= | Splice Region (SNP) | VAF 16/77 reads (21%) | catalogued as COSV60824966; called by muse, mutect2, varscan2
- CASD1 | c.1132A>G p.M378V | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51971932; called by muse, mutect2, varscan2
- CBLL1 | c.419del p.K140Rfs*52 | Frame Shift Del (DEL) | VAF 24/162 reads (15%) | catalogued as rs1256378164; called by mutect2, varscan2
- CC2D2A | c.1250A>G p.H417R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67503200; called by muse, mutect2, varscan2
- CCAR2 | c.446T>C p.I149T | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV51515022; called by muse, mutect2, varscan2
- CCAR2 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as rs1319530949, COSV52383916; called by muse, mutect2, varscan2
- CCDC170 | c.1914del p.K638Nfs*24 | Frame Shift Del (DEL) | VAF 33/171 reads (19%) | catalogued as rs751612825; called by mutect2, pindel, varscan2
- CCDC57 | c.1081T>A p.S361T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.109); catalogued as COSV58934819; called by muse, mutect2, varscan2
- CCDC80 | c.1599del p.A534Qfs*21 | Frame Shift Del (DEL) | VAF 18/148 reads (12%) | catalogued as rs1414623331; called by mutect2, pindel, varscan2
- CCDC85A | c.1571A>G p.K524R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV68149828; called by muse, mutect2, varscan2
- CCL7 | c.23T>G p.L8R | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52336877; called by muse, mutect2, varscan2
- CCN4 | c.424T>C p.Y142H | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV51531033; called by muse, mutect2, varscan2
- CCN4 | c.609C>T p.F203= | Splice Region (SNP) | VAF 13/101 reads (13%) | catalogued as rs773458131, COSV51529381; called by muse, mutect2, varscan2
- CCN5 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 13/81 reads (16%) | catalogued as rs917407124, COSV51936908; called by muse, mutect2, varscan2
- CCNF | c.767G>T p.W256L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.083); catalogued as COSV53539480; called by muse, mutect2, varscan2
- CCR3 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs756281359, COSV100656543, COSV62462751; called by muse, mutect2, varscan2
- CD38 | c.401A>G p.Q134R | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.02); catalogued as COSV56889794; called by muse, mutect2, varscan2
- CDC7 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 13/106 reads (12%) | catalogued as rs1406898199, COSV52309379; called by muse, mutect2, varscan2
- CDH12 | c.1988A>G p.E663G | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66399238; called by muse, mutect2, varscan2
- CDH12 | c.1676G>A p.R559H | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs763451842, COSV66399245; called by muse, mutect2, varscan2
- CDH17 | c.1315G>A p.V439I | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.384); catalogued as rs181733586, COSV50327433; called by muse, mutect2, varscan2
- CDH19 | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50957369; called by muse, mutect2, varscan2
- CDH20 | c.1081G>T p.E361* | Nonsense Mutation (SNP) | VAF 33/135 reads (24%) | catalogued as COSV53003755, COSV53008290, COSV99406679; called by muse, mutect2, varscan2
- CDH24 | c.2135del p.P712Rfs*129 | Frame Shift Del (DEL) | VAF 15/82 reads (18%) | catalogued as rs752398646; called by mutect2, pindel, varscan2
- CDH8 | c.1576A>C p.K526Q | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.026); catalogued as rs575023349, COSV54861581, COSV54885299; called by muse, mutect2, varscan2
- CDT1 | c.497A>C p.K166T | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV56347951; called by muse, mutect2
- CEACAM6 | c.156_158del p.L54del | In Frame Del (DEL) | VAF 34/211 reads (16%) | catalogued as rs782687381; called by pindel, varscan2
- CEP152 | c.3100C>T p.R1034W | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs184240876, COSV57858650; called by muse, mutect2, varscan2
- CEP152 | c.3098A>G p.K1033R | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs866569090, COSV57858666; called by muse, mutect2
- CFI | c.1650_1651del p.C550Wfs*17 | Frame Shift Del (DEL) | VAF 76/464 reads (16%) | catalogued as rs774728696; called by pindel, varscan2
- CGRRF1 | c.305G>T p.C102F | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53596444; called by muse, mutect2, varscan2
- CHD1 | c.3960del p.E1321Kfs*22 | Frame Shift Del (DEL) | VAF 32/203 reads (16%) | catalogued as rs1561489348; called by pindel, varscan2
- CHD6 | c.2500C>T p.R834W | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58553262; called by muse, mutect2, varscan2
- CHD7 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 52/344 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as COSV71109310; called by muse, mutect2, varscan2
- CHD7 | c.5816G>A p.R1939Q | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as rs1024797402, COSV71107652; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHEK1 | c.676del p.T226Hfs*14 | Frame Shift Del (DEL) | VAF 28/147 reads (19%) | catalogued as rs757716680, COSV54024545; called by mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 35/78 reads (45%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNB3 | c.1069T>C p.S357P | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV51494505; called by muse, mutect2, varscan2
- CHST8 | c.770T>A p.V257D | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52858164; called by muse, mutect2, varscan2
- CLASP2 | c.3799G>A p.D1267N (on ENST00000359576; = p.D1266N on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV56280505; called by muse, varscan2
- CLCN1 | c.132del p.H44Qfs*33 | Frame Shift Del (DEL) | VAF 16/172 reads (9%) | catalogued as COSV58370371; called by mutect2, pindel
- CLDN10 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs1375647652, COSV65297185; called by muse, mutect2, varscan2
- CLDN10 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.037); catalogued as COSV54824092; called by muse, mutect2
- CLDN19 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs377319583; ClinVar: uncertain significance; called by mutect2, varscan2
- CLN3 | c.1160C>T p.A387V (on ENST00000360019 / NM_001286104.2; = p.A411V on NM_000086.2) | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.068); catalogued as COSV100343632; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 20/104 reads (19%) | catalogued as rs369752219; called by mutect2, varscan2
- CLTCL1 | c.320_322del p.E107del | In Frame Del (DEL) | VAF 9/58 reads (16%) | catalogued as rs1364607252; called by pindel, varscan2
- CMTM1 | c.452C>T p.S151F (on ENST00000457188 / NM_181269.3; = p.S268F on NM_052999.4) | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV51748430; called by muse, mutect2, varscan2
- CMTR1 | c.2126T>C p.L709P | Missense Mutation (SNP) | VAF 51/288 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs773260261, COSV65090132; called by muse, mutect2, varscan2
- CNGB1 | c.3069A>C p.K1023N | Missense Mutation (SNP) | VAF 82/335 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV51899931; called by muse, mutect2, varscan2
- CNTN2 | c.1772C>T p.T591M | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1384499327, COSV59349482; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | catalogued as rs374805044; called by mutect2, varscan2
- COL11A1 | c.3100C>T p.L1034F | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.621); catalogued as rs866324545, COSV62180433; called by muse, mutect2, varscan2
- COL12A1 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV59394093; called by muse, mutect2, varscan2
- COL20A1 | c.2683del p.L895Yfs*27 | Frame Shift Del (DEL) | VAF 12/75 reads (16%) | catalogued as rs1339972284; called by mutect2, pindel, varscan2
- COL6A2 | c.1108G>T p.G370C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56003212; called by mutect2, varscan2
- COL7A1 | c.5976G>T p.K1992N | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV60394219; called by muse, mutect2, varscan2
- COQ7 | c.75T>G p.A25= | Splice Region (SNP) | VAF 44/184 reads (24%) | catalogued as COSV58981558; called by muse, mutect2, varscan2
- CPAMD8 | c.3153dup p.H1052Afs*30 (on ENST00000651564; = p.H1005Afs*30 on NM_015692.5) | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | catalogued as rs750161916; called by mutect2, varscan2
- CPEB2 | c.2297G>A p.R766H | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs1185406169, COSV52591091; called by muse, mutect2, varscan2
- CPNE1 | c.992A>G p.D331G (on ENST00000352393; = p.D336G on NM_003915.5) | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs972376737, COSV58290291; called by muse, mutect2, varscan2
- CPPED1 | c.470del p.G157Afs*21 | Frame Shift Del (DEL) | VAF 16/81 reads (20%) | catalogued as rs758254494; called by mutect2, pindel, varscan2
- CR1 | c.3843G>T p.K1281N | Missense Mutation (SNP) | VAF 84/375 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV65457544; called by muse, varscan2
- CR1 | c.4955C>T p.P1652L | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.083); catalogued as rs561028518, COSV65457546; called by muse, mutect2, varscan2
- CRACD | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 68/329 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746752030, COSV51716359; called by muse, mutect2, varscan2
- CRHBP | c.333+2T>C p.X111_splice | Splice Site (SNP) | VAF 15/52 reads (29%) | catalogued as COSV57188219; called by muse, mutect2, varscan2
- CRYBA1 | c.461T>C p.F154S | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.251); catalogued as COSV56600714; called by muse, mutect2, varscan2
- CSF3R | c.2353A>G p.K785E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as COSV58965511, COSV58973172; called by muse, mutect2, varscan2
- CSMD1 | c.3662C>T p.P1221L (on ENST00000520002; = p.P1220L on NM_033225.6) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs777083383, COSV59276597, COSV59310638; called by muse, mutect2, varscan2
- CSNK2A1 | c.528G>T p.W176C | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53934760, COSV53935527; called by muse, mutect2, varscan2
- CSPG4 | c.3476G>A p.R1159H | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773421645, COSV57893777; called by muse, mutect2, varscan2
- CSPG4 | c.1826C>A p.P609H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57893787; called by muse, varscan2
- CTAGE1 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs372127240; called by muse, mutect2, varscan2
- CTDSP1 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1459655218, COSV56089790; called by muse, mutect2, varscan2
- CTNND1 | c.1330A>T p.K444* | Nonsense Mutation (SNP) | VAF 92/453 reads (20%) | catalogued as COSV62383083; called by muse, mutect2, varscan2
- CTSA | c.990del p.C331Afs*36 | Frame Shift Del (DEL) | VAF 12/71 reads (17%) | catalogued as rs758642867; called by mutect2, pindel, varscan2
- CTTN | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs534661512, COSV57231713; called by muse, mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 13/110 reads (12%) | catalogued as rs756254049; called by mutect2, pindel, varscan2
- CYP19A1 | c.1169A>G p.K390R | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.117); catalogued as COSV53058449; called by muse, mutect2, varscan2
- CYP26C1 | c.1241C>T p.T414M | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53652261; called by muse, mutect2, varscan2
- CYP4F22 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs756447723, COSV54107951; called by muse, mutect2, varscan2
- CYP4F22 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as rs755273482, COSV54107959; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DACH1 | c.1460G>A p.R487H (on ENST00000619232 / NM_001366712.1; = p.R435H on NM_080759.6) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1192436758, COSV57496625; called by muse, mutect2
- DAG1 | c.1723T>C p.Y575H | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58183663; called by muse, mutect2, varscan2
- DAGLB | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs1562479268, COSV51702858, COSV51703371; called by muse, mutect2, varscan2
- DCDC1 | c.748del p.I250Lfs*7 | Frame Shift Del (DEL) | VAF 47/222 reads (21%) | catalogued as rs1565584055; called by mutect2, pindel, varscan2
- DCDC2 | c.1328C>A p.A443D | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV65828593; called by muse, mutect2, varscan2
- DCST2 | c.1352T>C p.L451S | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV55051168; called by muse, mutect2, varscan2
- DDX24 | c.1166T>G p.L389R | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV58212254; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 30/156 reads (19%) | catalogued as rs766714372; called by mutect2, varscan2
- DENND6A | c.1649C>G p.T550R | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.347); catalogued as rs1225776041, COSV60768328; called by muse, mutect2, varscan2
- DENND6A | c.1074del p.F358Lfs*14 | Frame Shift Del (DEL) | VAF 20/109 reads (18%) | catalogued as rs34959359; called by mutect2, pindel, varscan2
- DEPDC5 | c.3461del p.G1154Afs*7 (on ENST00000400246; = p.G1223Afs*7 on NM_014662.5) | Frame Shift Del (DEL) | VAF 35/290 reads (12%) | catalogued as COSV99836875; called by mutect2, pindel, varscan2
- DHCR7 | c.1293C>G p.F431L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV62794926; called by muse, mutect2, varscan2
- DHRS9 | c.669del p.K223Nfs*25 | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | catalogued as rs756920263; called by mutect2, varscan2
- DHX15 | c.1080G>T p.E360D | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.913); catalogued as COSV100391673; called by muse, mutect2, varscan2
- DHX29 | c.889del p.I297* | Frame Shift Del (DEL) | VAF 23/114 reads (20%) | catalogued as rs754176557, COSV99287116; called by mutect2, pindel, varscan2
- DHX36 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773134906, COSV57671550; called by muse, mutect2, varscan2
- DHX36 | c.460del p.M154Cfs*27 | Frame Shift Del (DEL) | VAF 20/126 reads (16%) | catalogued as rs373108427; called by mutect2, varscan2
- DHX37 | c.3145G>A p.A1049T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as rs755379720, COSV58133152; called by muse, mutect2, varscan2
- DIAPH3 | c.1322T>G p.L441R (on ENST00000400324 / NM_001042517.2; = p.L178R on NM_030932.3) | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57368696; called by muse, mutect2
- DLG2 | c.260T>C p.V87A | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.377); catalogued as COSV54637278; called by muse, mutect2, varscan2
- DMRTB1 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65112926; called by muse, mutect2
- DNAH7 | c.10262T>C p.F3421S | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56760351; called by muse, mutect2, varscan2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 24/118 reads (20%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAH9 | c.9572C>T p.A3191V | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1011796626, COSV52332537; called by muse, mutect2, varscan2
- DNAJB7 | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV53421529; called by muse, mutect2, varscan2
- DNAJC21 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1477361660, COSV57759990; called by muse, mutect2, varscan2
- DNAJC6 | c.1171C>A p.L391I | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54773364, COSV99675250; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 9/69 reads (13%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK4 | c.1646A>G p.K549R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV70235692; called by muse, mutect2, varscan2
- DOCK8 | c.3339del p.F1113Lfs*2 | Frame Shift Del (DEL) | VAF 13/82 reads (16%) | catalogued as rs748134881; called by mutect2, varscan2
- DPY19L2 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs1243921431, COSV60542895; called by muse, mutect2, varscan2
- DRC7 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs778818941, COSV61054218; called by muse, mutect2, varscan2
- DRD5 | c.773G>T p.R258M | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as COSV58577642; called by muse, mutect2, varscan2
- DSE | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs112379267; called by muse, mutect2, varscan2
- DST | c.1325G>A p.R442H (on ENST00000361203 / NM_001374722.1; = p.R116H on NM_001723.6) | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs751086390, COSV55009302; called by muse, mutect2, varscan2
- DUSP16 | c.1622C>T p.S541L | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as rs769177105, COSV53807301; called by muse, mutect2, varscan2
- DYNC1I2 | c.232dup p.S78Ffs*2 | Frame Shift Ins (INS) | VAF 11/40 reads (28%) | catalogued as rs749854400; called by mutect2, pindel, varscan2
- DYNC2H1 | c.9050T>G p.L3017R | Missense Mutation (SNP) | VAF 4/77 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62092114; called by muse, mutect2
- EAF2 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs777157009, COSV56544086; called by muse, mutect2, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 28/92 reads (30%) | catalogued as rs369293935; called by mutect2, varscan2
- EEF2K | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs143471765; called by muse, mutect2, varscan2
- EGR1 | c.602C>A p.P201H | Missense Mutation (SNP) | VAF 67/304 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); catalogued as COSV53518906; called by muse, mutect2, varscan2
- EHMT1 | c.2023G>A p.A675T | Missense Mutation (SNP) | VAF 66/337 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1275795367, COSV58373914; called by muse, mutect2, varscan2
- EIF2A | c.1049A>G p.K350R | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.521); catalogued as rs769898889, COSV56406021; called by muse, mutect2, varscan2
- EIF2B4 | c.364C>T p.Q122* (on ENST00000347454 / NM_001034116.2; = p.Q121* on NM_015636.3) | Nonsense Mutation (SNP) | VAF 41/163 reads (25%) | catalogued as COSV52007383; called by muse, varscan2
- EIF3H | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52666034; called by muse, mutect2, varscan2
- EIF4B | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as rs374072301; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201513059; called by muse, varscan2
- ELAVL1 | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 7/193 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60966114, COSV60966287; called by muse, mutect2
- EPB41L4A | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV54867608; called by muse, mutect2, varscan2
- EPHA5 | c.1891G>T p.E631* | Nonsense Mutation (SNP) | VAF 13/82 reads (16%) | catalogued as COSV56633589, COSV56640546; called by muse, mutect2, varscan2
- EPHB1 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as rs373293977; called by muse, mutect2, varscan2
- EPHB2 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as rs771598124, COSV65861848, COSV65864620; called by muse, mutect2, varscan2
- EPPK1 | c.2515T>G p.S839A | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV73261075; called by muse, mutect2, varscan2
- EPRS1 | c.4277T>C p.V1426A | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV65098431; called by muse, mutect2, varscan2
- EPSTI1 | c.292A>T p.N98Y | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV58044997; called by muse, mutect2, varscan2
- ERC1 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs776030209, COSV61693850; called by muse, mutect2, varscan2
- ERCC4 | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 42/272 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149364215, CM133659, COSV61311654; called by muse, mutect2, varscan2
- ERGIC2 | c.715del p.I239Lfs*3 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | catalogued as rs1178968638; called by mutect2, pindel, varscan2
- ESR2 | c.977A>G p.D326G | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV50829917; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 18/128 reads (14%) | catalogued as rs775950025; called by mutect2, varscan2
- ETV6 | c.325T>G p.S109A | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV67149413; called by muse, mutect2, varscan2
- EVX2 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1216336490, COSV57963050; called by muse, mutect2
- EXTL2 | c.42G>T p.M14I | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.014); catalogued as COSV64472976; called by muse, mutect2, varscan2
- EYS | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.735); catalogued as COSV60982783; called by muse, mutect2, varscan2
- EZH2 | c.1985T>C p.M662T (on ENST00000460911 / NM_001203247.2; = p.M667T on NM_004456.5) | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV57451167; called by muse, mutect2, varscan2
- F13A1 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 59/302 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as rs749947217, COSV53557177; called by muse, mutect2, varscan2
- F13B | c.965C>T p.T322I | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1478491925, COSV66373425; called by muse, mutect2, varscan2
- F9 | c.449A>G p.D150G | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1224210668, CD005439, COSV54379832; called by muse, mutect2, varscan2
- FAAP100 | c.2486A>G p.Y829C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV58367240; called by muse, varscan2
- FABP6 | c.309G>T p.E103D | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV67436896, COSV67437587; called by muse, mutect2, varscan2
- FAM111A | c.1477C>T p.R493* | Nonsense Mutation (SNP) | VAF 20/145 reads (14%) | catalogued as rs761191576, COSV64655258; called by muse, mutect2, varscan2
- FAM120A | c.2516G>A p.R839H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1346083999, COSV52903994; called by muse, mutect2, varscan2
- FAM135B | c.1003C>A p.L335I | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52709941, COSV52718668; called by muse, mutect2, varscan2
- FAM160B1 | c.995T>C p.V332A | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.356); catalogued as COSV65087895; called by muse, mutect2, varscan2
- FAM160B2 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs762967634, COSV57157944; called by muse, mutect2, varscan2
- FAM199X | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV55433483; called by muse, mutect2, varscan2
- FAM217B | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771303298, COSV62564164; called by muse, mutect2, varscan2
- FAM47A | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.364); catalogued as rs745403635, COSV60495820; called by muse, mutect2, varscan2
- FAM47C | c.119T>C p.F40S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.798); catalogued as rs1458505872, COSV63725897; called by muse, mutect2, varscan2
- FAM83H | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs782447687, COSV66353726; called by muse, mutect2
- FANCD2 | c.3584G>A p.S1195N | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as COSV55036376; called by muse, mutect2, varscan2
- FAP | c.2032A>G p.K678E | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV51861079; called by muse, mutect2, varscan2
- FAR2 | c.956-1G>A p.X319_splice | Splice Site (SNP) | VAF 35/215 reads (16%) | catalogued as COSV51725068; called by muse, mutect2, varscan2
- FBLN1 | c.1990C>T p.R664W | Missense Mutation (SNP) | VAF 77/522 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs748201606, COSV59937239; called by muse, mutect2, varscan2
- FBN3 | c.3545G>A p.G1182E | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.782); catalogued as COSV54458576; called by muse, mutect2, varscan2
- FBXO43 | c.377del p.K126Rfs*33 | Frame Shift Del (DEL) | VAF 38/294 reads (13%) | catalogued as rs1406026740; called by mutect2, varscan2
- FCRL3 | c.814del p.R272Gfs*3 | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | catalogued as rs1288807478; called by mutect2, varscan2
- FCRLA | c.622G>T p.G208* (on ENST00000367959; = p.G185* on NM_032738.4) | Nonsense Mutation (SNP) | VAF 109/409 reads (27%) | catalogued as COSV52685391; called by muse, mutect2, varscan2
- FDPS | c.736del p.Q246Rfs*31 | Frame Shift Del (DEL) | VAF 21/104 reads (20%) | catalogued as rs1557981615; called by mutect2, pindel, varscan2
- FECH | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50490683; called by muse, mutect2, varscan2
- FETUB | c.386T>C p.V129A | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as rs1262593996, COSV54005358; called by muse, mutect2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 82/262 reads (31%) | catalogued as rs748969702; called by mutect2, varscan2
- FGFR1 | c.1408C>T p.R470C (on ENST00000447712 / NM_023110.3; = p.R468C on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs781310679, COSV58332647; called by muse, mutect2, varscan2
- FGFR1 | c.1055A>G p.H352R (on ENST00000447712 / NM_023110.3; = p.H350R on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as COSV58332687; called by muse, mutect2, varscan2
- FHOD1 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as COSV99264459; called by muse, mutect2, varscan2
- FHOD3 | c.2683C>T p.R895C (on ENST00000359247 / NM_001281739.3; = p.R912C on NM_025135.5) | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761939836, COSV57171133; called by muse, mutect2, varscan2
- FMOD | c.1006G>A p.V336M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as rs376930920; called by muse, mutect2, varscan2
- FMOD | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369136071; called by muse, mutect2, varscan2
- FOCAD | c.1240A>G p.T414A | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV58097294; called by muse, mutect2, varscan2
- FOXA3 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs779323164, COSV56215556; called by muse, mutect2, varscan2
- FOXL2 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as COSV57726586; called by muse, mutect2, varscan2
- FOXP1 | c.862A>G p.R288G | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); catalogued as rs1248474859, COSV59540249; called by muse, mutect2, varscan2
- FOXR1 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.916); catalogued as rs117450447, COSV57651899; called by muse, mutect2, varscan2
- FRAS1 | c.8431A>C p.S2811R | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as COSV53604352; called by muse, mutect2
- FREM1 | c.934C>A p.L312M | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63087269; called by muse, mutect2, varscan2
- FRS2 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.249); catalogued as rs769491241, COSV54724649; called by muse, mutect2, varscan2
- FRY | c.2782C>T p.P928S | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV66568599; called by muse, mutect2, varscan2
- FRY | c.6976A>G p.K2326E | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66568605; called by muse, mutect2, varscan2
- FRY | c.8324G>A p.S2775N | Missense Mutation (SNP) | VAF 60/288 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.83); catalogued as COSV66568611; called by muse, mutect2, varscan2
- FSTL3 | c.665G>A p.C222Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51261532; called by muse, mutect2, varscan2
- FSTL4 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs374211071; called by muse, mutect2, varscan2
- FTSJ3 | c.703_705del p.K235del | In Frame Del (DEL) | VAF 15/92 reads (16%) | catalogued as rs745787698; called by pindel, varscan2
- FUT9 | c.884C>A p.P295H | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56142527, COSV56145462; called by muse, mutect2, varscan2
- FZD4 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as rs374499509; called by muse, mutect2, varscan2
- FZD6 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs754581593, COSV62471193; called by muse, mutect2, varscan2
- GABRP | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.352); catalogued as rs150667747; called by muse, mutect2, varscan2
- GALNT14 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.053); catalogued as rs149431826; called by muse, mutect2, varscan2
- GALNT14 | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61104331; called by muse, mutect2, varscan2
- GATAD2A | c.691T>C p.S231P | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV53068848; called by muse, mutect2, varscan2
- GCAT | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs771397291, COSV50648877; called by muse, mutect2, varscan2
- GKN1 | c.140A>C p.N47T | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV65006435; called by muse, mutect2, varscan2
- GLB1L2 | c.1735A>C p.N579H | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753321111, COSV56996292; called by muse, mutect2, varscan2
- GLIS3 | c.2209A>G p.S737G | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749999750, COSV60927676; called by muse, mutect2, varscan2
- GLP1R | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs199523424, COSV64714792; called by muse, mutect2, varscan2
- GNAI3 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs758640921, COSV63983596; called by muse, mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 33/170 reads (19%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GNMT | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.077); catalogued as rs768654043, COSV55102776; called by muse, mutect2, varscan2
- GOLGA2 | c.2669G>A p.R890K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV57850637; called by muse, mutect2, varscan2
- GOT1 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 69/368 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as COSV63201265; called by muse, mutect2, varscan2
- GPCPD1 | c.67T>C p.C23R | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV66830598; called by muse, mutect2, varscan2
- GPR135 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.464); catalogued as COSV67749574, COSV67749900; called by muse, mutect2, varscan2
- GPR135 | c.1000C>A p.L334I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV101229345; called by muse, mutect2, varscan2
- GPR137 | c.835A>G p.I279V | Missense Mutation (SNP) | VAF 52/291 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.147); catalogued as COSV57401860; called by muse, mutect2, varscan2
- GPR158 | c.2644G>A p.A882T | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141827771, COSV66269338; called by muse, mutect2, varscan2
- GPR19 | c.1109del p.N370Tfs*59 | Frame Shift Del (DEL) | VAF 58/214 reads (27%) | catalogued as rs1416935976; called by mutect2, varscan2
- GPR37 | c.541del p.Y181Tfs*65 | Frame Shift Del (DEL) | VAF 19/138 reads (14%) | catalogued as COSV58259789; called by mutect2, pindel, varscan2
- GPR45 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs746939000, COSV51523283, COSV51525996; called by muse, mutect2, varscan2
- GRHL2 | c.650G>A p.S217N | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV52547471; called by muse, mutect2, varscan2
- GRIN2A | c.945G>T p.E315D | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.814); catalogued as COSV58029119; called by muse, mutect2, varscan2
- GRIN2C | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs768767640, COSV53111567; called by muse, mutect2, varscan2
- GRM6 | c.2209C>A p.Q737K | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV51439196; called by muse, mutect2, varscan2
- GRM6 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.066); catalogued as rs377276357; called by muse, mutect2, varscan2
- GRM6 | c.727dup p.V243Gfs*40 | Frame Shift Ins (INS) | VAF 40/264 reads (15%) | catalogued as rs281865186; ClinVar: not provided; called by mutect2, varscan2
- GRM8 | c.2261G>A p.G754E | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.886); catalogued as COSV58819299; called by muse, mutect2, varscan2
- GRN | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs533451404, CM085454, COSV50006838; called by muse, mutect2, varscan2
- GTDC1 | c.25T>C p.F9L | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53993134; called by muse, mutect2, varscan2
- GYS1 | c.1279A>G p.M427V | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs746669628, COSV54402368; called by muse, mutect2, varscan2
- H2BC3 | c.110G>T p.S37I | Missense Mutation (SNP) | VAF 41/289 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as COSV63550870; called by muse, mutect2, varscan2
- HCFC1 | c.2953C>A p.P985T | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV60071520; called by muse, mutect2, varscan2
- HDAC5 | c.2793del p.I932Lfs*14 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | catalogued as COSV52242263; called by mutect2, pindel, varscan2
- HDLBP | c.2294C>T p.A765V | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.093); catalogued as rs758748107, COSV60494455; called by muse, mutect2, varscan2
- HEATR3 | c.764-1G>C p.X255_splice | Splice Site (SNP) | VAF 11/60 reads (18%) | catalogued as COSV53528898; called by mutect2, varscan2
- HEATR4 | c.2488C>T p.R830W | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs760660588, COSV100408055, COSV58373864; called by muse, mutect2, varscan2
- HEATR5B | c.6214del p.*2072Nfs*3 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | catalogued as rs1315552549, COSV51848615; called by mutect2, varscan2
- HEATR6 | c.2258C>T p.A753V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51744970; called by muse, mutect2, varscan2
- HEATR9 | c.290A>T p.K97M | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1376221810; called by muse, mutect2, varscan2
- HECTD3 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs763879013, COSV55799863; called by muse, mutect2, varscan2
- HECTD4 | c.3335C>T p.A1112V | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs865930487, COSV61178769; called by muse, mutect2, varscan2
- HECW2 | c.2552A>C p.N851T | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as COSV53656521; called by muse, mutect2, varscan2
- HERC5 | c.292A>G p.K98E | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as COSV52039117; called by muse, mutect2, varscan2
- HID1 | c.803A>G p.Y268C | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59351392; called by muse, mutect2, varscan2
- HK1 | c.2558G>A p.R853H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs538768945, COSV53856672; called by mutect2, varscan2
- HLA-DRA | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs201781094, COSV66622681; called by muse, mutect2, varscan2
- HLA-G | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV64405474; called by muse, mutect2, varscan2
- HLA-G | c.627dup p.K210Qfs*11 | Frame Shift Ins (INS) | VAF 30/218 reads (14%) | catalogued as rs752829354; called by mutect2, varscan2
- HM13 | c.319A>G p.M107V | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.021); catalogued as rs1457093191, COSV59436873; called by muse, mutect2, varscan2
- HMGCLL1 | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV51443635, COSV51448205; called by muse, varscan2
- HMOX1 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV53339620; called by muse, mutect2, varscan2
- HOGA1 | c.853A>G p.I285V | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as COSV56729647; called by muse, mutect2, varscan2
- HOXB2 | c.272del p.P91Rfs*8 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs761024113; called by mutect2, varscan2
- HOXD12 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV66832391; called by muse, mutect2, varscan2
- HPS6 | c.1117G>T p.G373W | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV54625394; called by muse, mutect2, varscan2
- HSD3B7 | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 47/230 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV52680313; called by muse, mutect2, varscan2
- HTR6 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.666); catalogued as COSV57032889; called by muse, mutect2, varscan2
- IDO2 | c.466A>G p.I156V (on ENST00000389060; = p.I169V on NM_194294.2) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1468239864, COSV58424943; called by muse, mutect2
- IFIH1 | c.714G>T p.W238C | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.258); catalogued as COSV55126176; called by muse, mutect2, varscan2
- IFNAR2 | c.1349C>T p.S450L | Missense Mutation (SNP) | VAF 32/580 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.08); catalogued as rs866733383, COSV51615009; called by muse, mutect2
- IGFBP2 | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1469610584, COSV52080100, COSV99288274; called by muse, mutect2, varscan2
- IGSF5 | c.899G>A p.C300Y | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.93); PolyPhen benign (0.159); catalogued as COSV66029980; called by muse, varscan2
- IL36B | c.71T>C p.L24P | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV52085879; called by muse, mutect2, varscan2
- ILDR1 | c.863A>G p.Y288C (on ENST00000344209 / NM_001199799.2; = p.Y244C on NM_175924.4) | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99878894; called by muse, mutect2, varscan2
- IMPG1 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs142123216; called by muse, mutect2, varscan2
- INPPL1 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as rs762663532, COSV53354604; called by muse, mutect2, varscan2
- INSR | c.3560C>T p.T1187M | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs766867210, COSV57160921; called by muse, mutect2, varscan2
- IP6K2 | c.1001T>C p.I334T | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV53660614; called by muse, mutect2, varscan2
- IQGAP3 | c.2529A>G p.L843= | Splice Region (SNP) | VAF 55/262 reads (21%) | catalogued as COSV63250755; called by muse, mutect2, varscan2
- IRF5 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs887623136, COSV50857269; called by muse, mutect2, varscan2
- ITK | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201513154, COSV70061872; called by muse, mutect2, varscan2
- ITPR3 | c.7055A>G p.E2352G | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65291068; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | catalogued as rs755650243; called by mutect2, varscan2
- JAK2 | c.226+1G>A p.X76_splice | Splice Site (SNP) | VAF 15/97 reads (15%) | catalogued as COSV67601543; called by muse, mutect2, varscan2
- JAKMIP1 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.996); catalogued as COSV51528035; called by muse, mutect2, varscan2
- JMJD1C | c.5692G>A p.D1898N | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV59514187; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1129-2A>C p.X377_splice | Splice Site (SNP) | VAF 9/51 reads (18%) | catalogued as COSV59823488; called by muse, mutect2, varscan2
- JPH1 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.931); catalogued as COSV60610206; called by muse, mutect2, varscan2
- KCNA5 | c.356A>G p.H119R | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV52905185; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 37/228 reads (16%) | catalogued as rs752059864; called by mutect2, varscan2
- KCND1 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs147541534, COSV54413613; called by muse, mutect2, varscan2
- KCND2 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.789); catalogued as COSV58576728; called by muse, mutect2, varscan2
- KCNQ3 | c.2545G>A p.G849S | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.149); catalogued as rs761201259, COSV66468748, COSV66481582; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNS1 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV60259970; called by muse, mutect2, varscan2
- KCTD15 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52289817; called by muse, mutect2
- KCTD9 | c.974T>C p.L325P | Missense Mutation (SNP) | VAF 41/322 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55339814; called by muse, mutect2, varscan2
- KDM3B | c.2792A>G p.D931G | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV58689881; called by muse, mutect2, varscan2
- KDM6B | c.3337G>A p.G1113S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); catalogued as COSV54680463; called by muse, varscan2
- KDM7A | c.2572T>C p.Y858H | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.135); catalogued as COSV50090900; called by muse, mutect2, varscan2
- KEAP1 | c.932A>G p.H311R | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV50274684, COSV50325697, COSV50579650; called by muse, mutect2, varscan2
- KEL | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs61729041, CM973372, COSV62334383; called by muse, mutect2, varscan2
- KIAA0232 | c.1454G>T p.G485V | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV56924657; called by muse, mutect2, varscan2
- KIAA1841 | c.1784A>G p.K595R | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as COSV54374346; called by muse, mutect2, varscan2
- KIF13A | c.1588C>T p.R530* | Nonsense Mutation (SNP) | VAF 25/114 reads (22%) | catalogued as rs866916195, COSV52448138; called by muse, mutect2, varscan2
- KIF21A | c.2305del p.T769Qfs*5 (on ENST00000361418 / NM_001378440.1; = p.T756Qfs*5 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | catalogued as rs1219032396; called by mutect2, pindel
- KIF3B | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV65227344; called by muse, mutect2, varscan2
- KITLG | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57201050; called by muse, mutect2, varscan2
- KLB | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.215); catalogued as rs746215800, COSV57301212; called by muse, mutect2, varscan2
- KLHDC7A | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as COSV68769541; called by muse, mutect2, varscan2
- KLHDC7A | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68769544; called by muse, mutect2, varscan2
- KLHL40 | c.943T>C p.F315L | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV55133993; called by muse, mutect2, varscan2
- KLRC1 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs757144280, COSV61725093; called by muse, mutect2, varscan2
- KLRD1 | c.99T>A p.N33K | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as rs528896796, COSV60273476; called by muse, mutect2, varscan2
- KMT2D | c.3695C>T p.P1232L | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as rs1208909878, COSV56417703; called by muse, mutect2, varscan2
- KNOP1 | c.652del p.I218Sfs*41 | Frame Shift Del (DEL) | VAF 58/163 reads (36%) | catalogued as rs764099275; called by mutect2, varscan2
- KRT15 | c.99del p.S34Vfs*31 | Frame Shift Del (DEL) | VAF 17/98 reads (17%) | catalogued as COSV54178849; called by mutect2, pindel, varscan2
- KRT17 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs564768263, COSV100245236; called by mutect2, varscan2
- KRT222 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 19/514 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV67497906; called by muse, mutect2
- LAMA1 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67535491; called by muse, mutect2, varscan2
- LAMB1 | c.5125del p.T1709Lfs*22 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as rs1441388757; called by mutect2, pindel, varscan2
- LANCL1 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52064935; called by muse, mutect2, varscan2
- LGI3 | c.114del p.C39Afs*31 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs1232711946; called by mutect2, pindel
- LLGL1 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1373442315, COSV57497531; called by muse, mutect2, varscan2
- LLGL2 | c.986C>A p.T329N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51347998; called by muse, mutect2, varscan2
- LNPK | c.176T>C p.L59S | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as COSV55823376; called by muse, mutect2, varscan2
- LOXL3 | c.824del p.G275Afs*5 | Frame Shift Del (DEL) | VAF 42/154 reads (27%) | catalogued as rs746133895; called by mutect2, varscan2
- LRRFIP2 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs747194248, COSV60867217; called by muse, varscan2
- LRRK1 | c.1813C>A p.L605M | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52608425; called by muse, mutect2, varscan2
- LTF | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as rs1253218659, COSV51606145; called by muse, mutect2, varscan2
- LY6D | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs769479466, COSV56660984; called by muse, mutect2, varscan2
- MAGI1 | c.4238G>T p.R1413L | Missense Mutation (SNP) | VAF 48/228 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV58314766, COSV58322522; called by muse, varscan2
- MAGI1 | c.4207C>T p.R1403C | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.555); catalogued as COSV58322530; called by muse, varscan2
- MAGI1 | c.803T>C p.L268S | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as COSV100439007, COSV58322538; called by muse, mutect2, varscan2
- MAGIX | c.751T>A p.S251T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV66255911; called by muse, mutect2, varscan2
- MAN2B1 | c.250T>C p.Y84H | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54418135; called by muse, mutect2, varscan2
- MAP4K4 | c.2968C>T p.R990C (on ENST00000347699 / NM_001242559.2; = p.R908C on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56329706; called by muse, mutect2, varscan2
- MAPK15 | c.1302G>T p.K434N | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV62028004; called by muse, mutect2
- MAPK8IP3 | c.3274C>T p.R1092W | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1306450018, COSV51599872; called by muse, mutect2, varscan2
- MARK2 | c.1416G>A p.T472= (on ENST00000402010 / NM_001039469.2; = p.T471= on NM_004954.5) | Splice Region (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100158853, COSV100159094; called by muse, varscan2
- MARK3 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as rs763214749, COSV53509356; called by muse, mutect2, varscan2
- MAS1L | c.7T>C p.W3R | Missense Mutation (SNP) | VAF 12/66 reads (18%) | PolyPhen possibly damaging (0.608); catalogued as COSV65808810; called by muse, mutect2, varscan2
- MAVS | c.199G>A p.G67S | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs142867936; called by muse, mutect2, varscan2
- MC3R | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs552943206, COSV54763275; called by muse, mutect2, varscan2
- MCC | c.2452_2454del p.E818del | In Frame Del (DEL) | VAF 22/124 reads (18%) | catalogued as rs769125294; called by pindel, varscan2
- MCM10 | c.2102del p.N701Tfs*35 (on ENST00000484800 / NM_182751.3; = p.N700Tfs*35 on NM_018518.5) | Frame Shift Del (DEL) | VAF 17/94 reads (18%) | catalogued as rs772561920; called by mutect2, pindel, varscan2
- MCMDC2 | c.719T>C p.V240A | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV58035476; called by muse, mutect2
- MCOLN1 | c.594del p.E199Sfs*39 | Frame Shift Del (DEL) | VAF 51/282 reads (18%) | catalogued as rs1349755445, COSV51177134; called by mutect2, pindel, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | catalogued as rs1180255648; called by mutect2, pindel, varscan2
- MDN1 | c.9989T>A p.I3330N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV65520532; called by muse, mutect2, varscan2
- MEFV | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 21/102 reads (21%) | catalogued as rs768473920, COSV54819203; called by muse, mutect2, varscan2
- MIF4GD | c.440A>T p.E147V (on ENST00000325102 / NM_001370592.1; = p.E181V on NM_020679.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs765118124, COSV55453277; called by muse, mutect2, varscan2
- MLC1 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.99); catalogued as rs1362564136, COSV61116754; called by muse, mutect2, varscan2
- MLH3 | c.1755del p.E586Nfs*24 | Frame Shift Del (DEL) | VAF 35/188 reads (19%) | catalogued as rs751465048; called by mutect2, varscan2
- MLXIPL | c.2119C>T p.R707C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782546883, COSV57667844; called by muse, mutect2, varscan2
- MOB1B | c.567del p.F189Lfs*19 | Frame Shift Del (DEL) | VAF 29/161 reads (18%) | catalogued as rs778232663; called by mutect2, varscan2
- MOB2 | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1402632314, COSV57318120; called by muse, mutect2, varscan2
- MOXD1 | c.954A>G p.I318M | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.863); catalogued as COSV60943565, COSV60944618; called by muse, mutect2, varscan2
- MPRIP | c.1058dup p.A354Sfs*43 | Frame Shift Ins (INS) | VAF 6/23 reads (26%) | catalogued as rs778181735; called by mutect2, varscan2
- MRPL39 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV56260511; called by muse, mutect2, varscan2
- MRPS31 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 49/303 reads (16%) | catalogued as COSV60266672; called by muse, mutect2, varscan2
- MSR1 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs968882170, COSV50509712; called by muse, mutect2, varscan2
- MTCH2 | c.170A>G p.Y57C | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV56767035; called by muse, mutect2, varscan2
- MTF1 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779682329, COSV65988383; called by muse, mutect2, varscan2
- MTMR9 | c.584del p.N195Mfs*4 | Frame Shift Del (DEL) | VAF 16/137 reads (12%) | catalogued as rs767880823; called by mutect2, varscan2
- MUC17 | c.11279T>A p.V3760D | Missense Mutation (SNP) | VAF 61/373 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60286035; called by muse, mutect2, varscan2
- MUC4 | c.13241A>G p.Q4414R (on ENST00000463781 / NM_018406.7; = p.Q178R on NM_004532.6) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as COSV57776685; called by muse, mutect2, varscan2
- MUC5AC | c.14911G>A p.D4971N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.972); catalogued as COSV100611565; called by muse, mutect2
- MUC5B | c.15482T>C p.L5161P | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV71591409; called by muse, mutect2
- MUL1 | c.728T>C p.L243P | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749560449, COSV51641463; called by muse, mutect2, varscan2
- MYBPC2 | c.1882G>A p.V628M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.803); catalogued as rs747936523, COSV63094738; called by muse, mutect2, varscan2
- MYH9 | c.4954C>T p.R1652C | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1247989971, COSV53385023; called by muse, mutect2, varscan2
- MYO10 | c.3674del p.G1225Afs*22 | Frame Shift Del (DEL) | VAF 36/147 reads (24%) | catalogued as rs760302326; called by mutect2, varscan2
- MYO16 | c.3802G>A p.V1268I | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs377315850, COSV100695852; called by muse, mutect2, varscan2
- MYO16 | c.4100C>T p.S1367L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV62746605; called by muse, mutect2, varscan2
- MYO19 | c.2344C>T p.R782W (on ENST00000614623 / NM_001163735.1; = p.R582W on NM_025109.5) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs374496955; called by muse, mutect2
- MYO1C | c.2944C>T p.Q982* (on ENST00000648651 / NM_001080779.2; = p.Q947* on NM_033375.5) | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV62999006; called by muse, mutect2, varscan2
- MYO6 | c.343T>C p.Y115H | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV64118650; called by muse, mutect2, varscan2
- MYO9A | c.803T>C p.V268A | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61849849; called by muse, mutect2, varscan2
- MYOD1 | c.76A>G p.T26A | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51453299; called by muse, mutect2, varscan2
- NALCN | c.2579+1G>A p.X860_splice | Splice Site (SNP) | VAF 25/125 reads (20%) | catalogued as rs1020999876, COSV51930302; called by muse, mutect2, varscan2
- NCAN | c.778G>T p.G260C | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53049941; called by muse, mutect2, varscan2
- NCDN | c.1439T>A p.I480N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV61935432; called by muse, mutect2, varscan2
- NCOA3 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 18/144 reads (13%) | catalogued as rs762111371, COSV59067654; called by muse, mutect2, varscan2
- NCOA6 | c.1533G>A p.M511I | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.292); catalogued as COSV62862908; called by muse, mutect2
- NCOA7 | c.1600C>A p.P534T | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as COSV57654486; called by muse, mutect2, varscan2
- NDN | c.734T>C p.L245P | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59359450; called by muse, mutect2, varscan2
- NDST4 | c.632A>C p.E211A | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.023); catalogued as COSV52116304, COSV99996607; called by muse, mutect2, varscan2
- NDUFS1 | c.957G>T p.W319C | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51909109; called by muse, mutect2
- NEUROD6 | c.248del p.K83Rfs*35 | Frame Shift Del (DEL) | VAF 71/352 reads (20%) | catalogued as rs752284115; called by mutect2, varscan2
- NFASC | c.2072G>A p.R691Q (on ENST00000339876 / NM_001378329.1; = p.R687Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs151110151; called by muse, mutect2, varscan2
- NFATC2 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as COSV65355010; called by muse, mutect2
- NFIC | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59411567; called by muse, mutect2, varscan2
- NFIL3 | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 54/276 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as rs771637370, COSV52683560; called by muse, mutect2, varscan2
- NFKBIB | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.075); catalogued as rs778168546, COSV58003178; called by muse, mutect2, varscan2
- NLRC3 | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57089787; called by muse, mutect2, varscan2
- NLRP11 | c.2505G>T p.E835D | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV64086780; called by muse, varscan2
- NLRP11 | c.2450del p.N817Ifs*7 | Frame Shift Del (DEL) | VAF 30/174 reads (17%) | catalogued as COSV64089192; called by pindel, varscan2
- NLRP14 | c.643del p.Y215Ifs*10 | Frame Shift Del (DEL) | VAF 37/154 reads (24%) | catalogued as rs767663966; called by mutect2, pindel, varscan2
- NLRX1 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs1248882516, COSV99424806; called by muse, mutect2
- NOD1 | c.12G>T p.Q4H | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV56112056; called by muse, mutect2, varscan2
- NOLC1 | c.845T>C p.M282T | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1158309637, COSV64180289; called by muse, mutect2, varscan2
- NOP14 | c.1916G>T p.R639I | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV58624918; called by muse, mutect2, varscan2
- NOSTRIN | c.730-1G>A p.X244_splice (on ENST00000317647 / NM_001039724.4; = p.X166_splice on NM_052946.3) | Splice Site (SNP) | VAF 13/99 reads (13%) | catalogued as COSV58320764; called by muse, mutect2, varscan2
- NOTCH1 | c.5720C>T p.P1907L | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.776); catalogued as rs970443298, COSV53044741; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOTCH4 | c.5074A>G p.T1692A | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66680173; called by muse, mutect2, varscan2
- NPBWR1 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.657); catalogued as rs1448053086, COSV58695977; called by muse, mutect2, varscan2
- NPHS1 | c.2192G>A p.R731Q | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1402547024, COSV62287413; called by muse, mutect2, varscan2
- NPR3 | c.281C>A p.P94Q | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.676); catalogued as COSV54086600, COSV54088609; called by muse, mutect2, varscan2
- NR1I3 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV63467652; called by muse, mutect2, varscan2
- NR5A2 | c.172dup p.E58Gfs*15 | Frame Shift Ins (INS) | VAF 16/94 reads (17%) | catalogued as rs1406247186; called by mutect2, pindel, varscan2
- NRAP | c.4337A>G p.K1446R (on ENST00000359988 / NM_001322945.2; = p.K1411R on NM_006175.4) | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.228); catalogued as rs761315988, COSV63489793; called by muse, mutect2, varscan2
- NRBP2 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs375951915; called by muse, mutect2, varscan2
- NRIP1 | c.902T>C p.M301T | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59656778; called by muse, mutect2, varscan2
- NRROS | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.112); catalogued as rs750490618, COSV60745509; called by muse, mutect2, varscan2
- NSMF | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 76/322 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1288914484, COSV52997646; called by muse, mutect2, varscan2
- NSUN4 | c.878+1G>A p.X293_splice | Splice Site (SNP) | VAF 37/202 reads (18%) | catalogued as rs142333016; called by muse, mutect2, varscan2
- NUGGC | c.1892del p.N631Ifs*3 | Frame Shift Del (DEL) | VAF 50/344 reads (15%) | catalogued as rs755498396, COSV58439694; called by mutect2, varscan2
- NUP107 | c.429G>T p.E143D | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.917); catalogued as COSV57494302; called by muse, mutect2, varscan2
- NUP107 | c.1025A>G p.D342G | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57494306; called by muse, mutect2, varscan2
- NUP50 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs751626638, COSV100754393; called by muse, mutect2, varscan2
- NUP85 | c.1805G>A p.R602Q | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs746799719, COSV55456247; called by muse, mutect2, varscan2
- OMP | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs782325915, COSV53687241; called by muse, mutect2, varscan2
- OPA3 | c.181A>G p.M61V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV54398718; called by muse, mutect2, varscan2
- OR10G7 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100390040; called by muse, mutect2, varscan2
- OR10Z1 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); catalogued as COSV63524507; called by muse, mutect2, varscan2
- OR13A1 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751799752, COSV65572238; called by muse, mutect2, varscan2
- OR4C15 | c.379T>A p.S127T (on ENST00000314644; = p.S73T on NM_001001920.2) | Missense Mutation (SNP) | VAF 64/320 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.329); catalogued as rs1365786004, COSV58951546, COSV58952166; called by muse, mutect2, varscan2
- OR4K1 | c.84del p.F28Lfs*6 | Frame Shift Del (DEL) | VAF 79/670 reads (12%) | catalogued as COSV99578988; called by mutect2, pindel, varscan2
- OR51B5 | c.703G>C p.A235P | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV56175725; called by muse, mutect2, varscan2
- OR52H1 | c.871C>A p.P291T (on ENST00000322653; = p.P297T on NM_001005289.1) | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59505185; called by muse, mutect2, varscan2
- OR5H14 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 201/810 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV71193828; called by muse, mutect2, varscan2
- OR6C2 | c.647A>G p.Y216C | Missense Mutation (SNP) | VAF 54/258 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.929); catalogued as COSV59515857; called by muse, mutect2, varscan2
- OR8B8 | c.704C>A p.S235Y | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.053); catalogued as COSV60144119, COSV60144354; called by muse, varscan2
- ORC1 | c.1822C>T p.R608* | Nonsense Mutation (SNP) | VAF 15/93 reads (16%) | catalogued as rs1368174201, COSV65363715; called by muse, mutect2, varscan2
- OSBPL3 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs749326073, COSV57655492; called by mutect2, varscan2
- OTOP1 | c.1797G>C p.M599I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56392503; called by muse, mutect2, varscan2
- P2RY12 | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1374555502, COSV56375884; called by muse, mutect2, varscan2
- PABPC1L | c.1667G>A p.R556H | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs370341823; called by muse, mutect2, varscan2
- PAN3 | c.1612G>A p.D538N | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as rs370366529, COSV56703745; called by muse, mutect2, varscan2
- PAPSS2 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63263159; called by muse, varscan2
- PAQR9 | c.820T>G p.F274V | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV61417963; called by muse, mutect2
- PARP4 | c.2518C>T p.L840F | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV67961433; called by muse, mutect2, varscan2
- PBX3 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as rs1280344617, COSV60731536; called by muse, mutect2, varscan2
- PCDH1 | c.3427C>A p.R1143S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.89); catalogued as COSV54613353; called by muse, mutect2, varscan2
- PCDH8 | c.2984G>A p.R995Q | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.92); catalogued as rs759232639, COSV58812134; called by muse, mutect2, varscan2
- PCDHA11 | c.2195C>T p.A732V | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs987284077, COSV56494066; called by muse, mutect2, varscan2
- PCDHA9 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65325518; called by muse, mutect2, varscan2
- PCDHGA8 | c.217C>T p.Q73* | Nonsense Mutation (SNP) | VAF 16/87 reads (18%) | catalogued as rs1376617687, COSV53931098; called by muse, mutect2, varscan2
- PCF11 | c.1398A>C p.K466N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV53530034; called by muse, mutect2, varscan2
- PCLO | c.3719del p.K1240Sfs*78 | Frame Shift Del (DEL) | VAF 100/648 reads (15%) | catalogued as COSV61638231; called by mutect2, varscan2
- PCLO | c.666G>T p.Q222H | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.939); catalogued as COSV61628687; called by muse, mutect2, varscan2
- PCNX2 | c.5752C>T p.Q1918* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as rs769435496, COSV50794034; called by muse, mutect2, varscan2
- PCNX4 | c.1339C>T p.R447W (on ENST00000406854 / NM_001330177.2; = p.R213W on NM_022495.5) | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as rs562315792, COSV58303530; called by muse, mutect2, varscan2
- PCOLCE | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs772512800, COSV56159893, COSV99775234; called by muse, mutect2, varscan2
- PCYOX1L | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs768976745, COSV51002395, COSV51005543; called by muse, mutect2, varscan2
- PDE10A | c.860A>G p.Y287C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63094901; called by muse, mutect2, varscan2
- PDE1A | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.836); catalogued as rs752732676, COSV59514461; called by muse, mutect2, varscan2
- PDE1C | c.239dup p.E81Rfs*6 | Frame Shift Ins (INS) | VAF 23/165 reads (14%) | catalogued as rs765099236; called by mutect2, pindel, varscan2
- PDE3B | c.1100T>C p.L367P | Missense Mutation (SNP) | VAF 41/230 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56382591; called by muse, mutect2, varscan2
- PDE6A | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV54926568; called by muse, mutect2, varscan2
- PDE7A | c.1179del p.K393Nfs*6 (on ENST00000401827 / NM_001242318.3; = p.K367Nfs*6 on NM_002603.4) | Frame Shift Del (DEL) | VAF 11/61 reads (18%) | catalogued as rs776556726; called by mutect2, varscan2
- PDIA2 | c.1493C>A p.P498H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs766759491, COSV51986180; called by muse, mutect2, varscan2
- PDPR | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.679); catalogued as COSV55350995; called by muse, mutect2, varscan2
- PGAM2 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as rs1392611950, COSV51977668; called by muse, mutect2, varscan2
- PGBD1 | c.2159T>A p.I720N | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV52552650; called by muse, mutect2, varscan2
- PHACTR4 | c.160del p.S54Vfs*12 (on ENST00000373839 / NM_001350159.2; = p.S64Vfs*12 on NM_023923.4) | Frame Shift Del (DEL) | VAF 32/116 reads (28%) | catalogued as rs761437290, COSV65783432; called by mutect2, varscan2
- PHKA2 | c.1223T>C p.I408T | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as rs1428613360, COSV66053408; called by muse, mutect2, varscan2
- PHKA2 | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66053413; called by muse, mutect2, varscan2
- PI4KA | c.3382C>T p.R1128C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55409040; called by muse, mutect2, varscan2
- PIGG | c.1453G>A p.A485T (on ENST00000453061 / NM_001127178.3; = p.A477T on NM_017733.4) | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.577); catalogued as COSV56317546; called by muse, mutect2, varscan2
- PIM1 | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65165253; called by muse, varscan2
- PIP4K2A | c.941del p.P314Qfs*8 | Frame Shift Del (DEL) | VAF 24/142 reads (17%) | catalogued as rs755454854; called by mutect2, pindel, varscan2
- PKD1L2 | c.710T>C p.L237P | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs778862070, COSV61414258; called by muse, mutect2, varscan2
- PLCXD1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.046); catalogued as COSV67541708; called by muse, mutect2, varscan2
- PLCXD2 | c.*36T>C | Splice Region (SNP) | VAF 49/169 reads (29%) | catalogued as COSV101208642; called by muse, mutect2, varscan2
- PLEC | c.10450G>A p.V3484M (on ENST00000322810 / NM_201380.4; = p.V3374M on NM_000445.5) | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs782748769, COSV59616754; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHG1 | c.958A>G p.S320G | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.833); catalogued as rs1256508126, COSV62046746; called by muse, mutect2, varscan2
- PLEKHG4B | c.3692G>A p.W1231* (on ENST00000283426; = p.W1587* on NM_052909.5) | Nonsense Mutation (SNP) | VAF 20/81 reads (25%) | catalogued as COSV52046255; called by muse, mutect2, varscan2
- PLEKHG5 | c.67C>G p.P23A | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61701346; called by muse, mutect2, varscan2
- PLEKHH3 | c.574del p.V192Wfs*6 | Frame Shift Del (DEL) | VAF 15/79 reads (19%) | catalogued as rs778393033; called by mutect2, pindel, varscan2
- PLRG1 | c.608A>G p.H203R | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57423236; called by muse, mutect2, varscan2
- PNPLA7 | c.3522del p.I1175Sfs*148 | Frame Shift Del (DEL) | VAF 13/79 reads (16%) | catalogued as rs761459630; called by mutect2, pindel
- POGLUT2 | c.232C>A p.P78T | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV57279237; called by muse, mutect2, varscan2
- POLD3 | c.898del p.R300Gfs*5 | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | catalogued as rs761423306, COSV55240660; called by mutect2, varscan2
- POLR1G | c.653del p.N218Ifs*4 | Frame Shift Del (DEL) | VAF 41/216 reads (19%) | catalogued as rs753626854; called by mutect2, varscan2
- POU3F2 | c.886G>A p.G296S | Missense Mutation (SNP) | VAF 73/471 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60408731; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.234); catalogued as rs1367862966, COSV53452226; called by muse, varscan2
- PPEF1 | c.1415G>A p.S472N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV62995531; called by muse, mutect2, varscan2
- PPP1R26 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.683); catalogued as COSV63355344, COSV63356682; called by muse, mutect2, varscan2
- PPP1R7 | c.758A>G p.N253S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV52144375; called by muse, mutect2, varscan2
- PPP2R1A | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs769334090, COSV59043773; called by muse, mutect2, varscan2
- PPP2R5A | c.*7del | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | catalogued as rs540232176; called by mutect2, varscan2
- PRAMEF20 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 105/504 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as rs904309797; called by muse, mutect2, varscan2
- PRG2 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 82/394 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs369365761; called by muse, mutect2, varscan2
- PRICKLE1 | c.686G>T p.R229M | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1308626806, COSV61542850; called by muse, mutect2, varscan2
- PRKAA2 | c.1082del p.P361Qfs*3 | Frame Shift Del (DEL) | VAF 17/128 reads (13%) | catalogued as COSV64802473; called by mutect2, pindel, varscan2
- PRKCI | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.264); catalogued as rs1428010723, COSV55516564; called by muse, mutect2, varscan2
- PRKDC | c.1714G>A p.V572I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs1184535587, COSV58049694; called by muse, mutect2
- PRKDC | c.1096T>C p.Y366H | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58049708; called by muse, mutect2
- PRKN | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs529808032, COSV58203788, COSV58274029; called by muse, mutect2, varscan2
- PRND | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs748124038, COSV59896409; called by muse, mutect2, varscan2
- PRPSAP2 | c.245T>C p.V82A | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV99264711; called by muse, mutect2, varscan2
- PRSS36 | c.2038del p.L680Wfs*6 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs771809480; called by mutect2, pindel
- PRSS54 | c.1159G>A p.V387M | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as rs571314356, COSV54685710; called by muse, mutect2, varscan2
- PRTG | c.3167del p.F1056Sfs*30 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | catalogued as rs768325902, COSV101221331; called by mutect2, varscan2
- PRUNE2 | c.2981A>G p.E994G | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV65040614; called by muse, mutect2, varscan2
- PRUNE2 | c.2009C>T p.A670V | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs543743813, COSV65040618; called by muse, mutect2, varscan2
- PSD3 | c.578del p.N193Ifs*11 | Frame Shift Del (DEL) | VAF 49/330 reads (15%) | catalogued as rs776786486, COSV58974718; called by mutect2, pindel, varscan2
- PSEN1 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs140189461, COSV56194104; called by muse, mutect2, varscan2
- PSMD8 | c.586C>A p.L196I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53056686; called by muse, mutect2, varscan2
- PTCHD3 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs747571467, COSV71256676; called by muse, mutect2, varscan2
- PTGDR | c.238A>G p.S80G | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60093588; called by muse, mutect2, varscan2
- PTPN2 | c.937T>C p.Y313H | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV58996371; called by muse, mutect2, varscan2
- PTPRA | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs773334274, COSV53780647; called by muse, mutect2, varscan2
- PTPRT | c.2948T>C p.I983T | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV61975350; called by muse, mutect2, varscan2
- PTPRU | c.3082C>T p.R1028C | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773999258, COSV60526181; called by muse, mutect2, varscan2
- PTPRZ1 | c.1168G>T p.A390S | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101099900, COSV66434986; called by muse, mutect2, varscan2
- PWWP2B | c.257del p.P86Lfs*100 | Frame Shift Del (DEL) | VAF 19/87 reads (22%) | catalogued as rs1234606471; called by mutect2, pindel, varscan2
- PXDN | c.2414C>T p.T805M | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs781527729, COSV53231725; called by muse, mutect2, varscan2
- PZP | c.3449T>C p.V1150A | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs867299283, COSV54358453; called by muse, mutect2, varscan2
- QSOX2 | c.1939G>A p.G647R | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.06); catalogued as rs754218036, COSV62393503, COSV62393610, COSV62394421; called by muse, mutect2, varscan2
- RAB25 | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as COSV63107909; called by muse, mutect2, varscan2
- RABGAP1 | c.2789del p.N930Tfs*15 | Frame Shift Del (DEL) | VAF 23/94 reads (24%) | catalogued as rs749213218, COSV101017169; called by mutect2, varscan2
- RABGGTA | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs373544140; called by muse, mutect2, varscan2
- RADIL | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs761912777, COSV68200325; called by muse, mutect2, varscan2
- RALBP1 | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs746254893, COSV50034886, COSV50035496; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1697A>C p.E566A | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.041); catalogued as COSV52786479; called by muse, mutect2, varscan2
- RARA | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54190838; called by muse, mutect2, varscan2
- RASAL1 | c.2143del p.D715Tfs*28 | Frame Shift Del (DEL) | VAF 22/123 reads (18%) | catalogued as COSV99921991; called by mutect2, pindel, varscan2
- RB1CC1 | c.1574A>C p.K525T | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV50246397; called by muse, mutect2, varscan2
- RBBP8 | c.1309C>A p.L437M | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as COSV59091936; called by muse, mutect2, varscan2
- RBM12B | c.1123T>G p.S375A | Missense Mutation (SNP) | VAF 51/350 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV66968093; called by muse, mutect2, varscan2
- RBM26 | c.2181del p.K727Nfs*5 (on ENST00000438737 / NM_001366735.2; = p.K700Nfs*5 on NM_022118.5) | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | catalogued as rs751690893; called by mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 22/103 reads (21%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM45 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | catalogued as rs1337825501, COSV53720632; called by muse, mutect2, varscan2
- RBM6 | c.2848A>G p.T950A | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV56481982; called by muse, mutect2, varscan2
- RBMXL2 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.052); catalogued as rs1399837056, COSV60979640; called by muse, mutect2, varscan2
- RECK | c.2310T>G p.S770R | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV65035148; called by muse, mutect2, varscan2
- RET | c.613A>G p.R205G | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1564490234, COSV60691879; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RET | c.3025A>G p.M1009V | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs1554820079, CM109934, COSV60691896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RHOB | c.25G>C p.V9L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV55355966; called by muse, mutect2, varscan2
- RIMKLA | c.1075C>T p.R359W | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.803); catalogued as rs369934711; called by muse, mutect2, varscan2
- RIMS1 | c.4042del p.S1348Pfs*49 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | catalogued as COSV99331025; called by mutect2, pindel, varscan2
- RIMS2 | c.3713A>G p.D1238G | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV51672969; called by muse, mutect2, varscan2
- RINL | c.833A>G p.Y278C (on ENST00000591812 / NM_001195833.2; = p.Y164C on NM_198445.4) | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV61574506; called by muse, mutect2, varscan2
- RIPK4 | c.2357C>A p.A786E (on ENST00000352483; = p.A738E on NM_020639.3) | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60185505, COSV60186807; called by muse, mutect2, varscan2
- RIPOR1 | c.2159A>G p.Q720R (on ENST00000379312 / NM_001193522.2; = p.Q716R on NM_024519.4) | Missense Mutation (SNP) | VAF 76/531 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV50221603; called by muse, mutect2, varscan2
- RLF | c.2252C>T p.A751V | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65651498; called by muse, mutect2, varscan2
- RLN2 | c.20del p.F7Sfs*4 | Frame Shift Del (DEL) | VAF 16/138 reads (12%) | catalogued as rs760343057; called by mutect2, varscan2
- RNASE6 | c.248T>G p.I83S | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as COSV58977408; called by muse, mutect2, varscan2
- RNASEL | c.827C>A p.A276E | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62376558; called by muse, mutect2, varscan2
- RNF145 | c.1502G>A p.R501Q (on ENST00000424310 / NM_001199383.2; = p.R529Q on NM_144726.2) | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV50865810; called by muse, mutect2, varscan2
- RNF175 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs772501325, COSV56841442; called by muse, mutect2, varscan2
- RNF213 | c.6349C>T p.R2117C | Missense Mutation (SNP) | VAF 63/388 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs774827247, COSV60395239, COSV60396962; called by muse, mutect2, varscan2
- RNF25 | c.821C>A p.P274H | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV55306891; called by muse, varscan2
- ROBO2 | c.3233del p.P1078Qfs*95 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs745519558, COSV100168583; called by mutect2, varscan2
- ROCK1 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV67695547; called by muse, mutect2, varscan2
- ROR2 | c.2327G>A p.S776N | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV65218357; called by muse, mutect2, varscan2
- RORC | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 70/353 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59092647, COSV59094637; called by muse, mutect2, varscan2
- RPA2 | c.782A>C p.D261A | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV57877481; called by muse, mutect2, varscan2
- RPAP2 | c.234+1G>A p.X78_splice | Splice Site (SNP) | VAF 17/81 reads (21%) | catalogued as COSV64860011, COSV64860230; called by muse, mutect2, varscan2
- RPGRIP1L | c.2900G>A p.R967H | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as rs754075998, COSV50905179; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 17/75 reads (23%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPRD1B | c.503A>G p.Q168R | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV65032672; called by muse, mutect2, varscan2
- RPS6KC1 | c.1769T>G p.L590R | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65298580; called by muse, mutect2, varscan2
- RPTOR | c.823C>A p.L275M | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV60807246; called by muse, mutect2, varscan2
- RRP8 | c.944T>C p.F315S | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54449320; called by muse, mutect2
- RSF1 | c.3437G>A p.R1146H | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs371428606; called by muse, varscan2
- RSRC1 | c.194+2T>G p.X65_splice | Splice Site (SNP) | VAF 9/80 reads (11%) | catalogued as COSV55827146; called by muse, mutect2
- RTN2 | c.776C>T p.T259M | Missense Mutation (SNP) | VAF 55/239 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV55593161; called by muse, mutect2, varscan2
- RTP3 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs752009052, COSV56123773; called by muse, mutect2, varscan2
- RUBCNL | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.503); catalogued as COSV100529351, COSV59787394; called by muse, mutect2, varscan2
- RUVBL1 | c.908A>G p.E303G | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59475683; called by muse, mutect2, varscan2
- RYR1 | c.9091G>A p.A3031T | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as rs756311466, COSV62094952; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.12203T>C p.I4068T (on ENST00000389232; = p.I4069T on NM_001036.6) | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66785230; called by muse, mutect2, varscan2
- S1PR4 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as rs762051085, COSV55739970; called by muse, mutect2, varscan2
- SAMD12 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 27/159 reads (17%) | catalogued as rs541912477, COSV59048685; called by muse, mutect2, varscan2
- SAMD9 | c.4645del p.I1549Sfs*10 | Frame Shift Del (DEL) | VAF 27/176 reads (15%) | catalogued as rs761819522; called by mutect2, pindel, varscan2
- SAMD9 | c.3259G>T p.A1087S | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.722); catalogued as COSV66074501; called by muse, mutect2, varscan2
- SATB1 | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58667566, COSV58668698; called by muse, mutect2, varscan2
- SATL1 | c.479G>A p.S160N (on ENST00000395409; = p.S347N on NM_001012980.2) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.61); catalogued as COSV60575864, COSV60576265; called by muse, mutect2, varscan2
- SBNO1 | c.3416del p.N1139Mfs*9 (on ENST00000420886; = p.N1138Mfs*9 on NM_018183.5) | Frame Shift Del (DEL) | VAF 34/138 reads (25%) | catalogued as rs765867975; called by mutect2, varscan2
- SCAMP2 | c.223del p.Q75Rfs*36 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | catalogued as rs1304394803, COSV51513780; called by mutect2, pindel, varscan2
- SCML2 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.513); catalogued as COSV52620373; called by muse, mutect2, varscan2
- SCN1A | c.4093G>T p.G1365C (on ENST00000303395 / NM_001202435.3; = p.G1354C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57667094; called by muse, mutect2, varscan2
- SDK1 | c.4981A>C p.M1661L | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as COSV67364962; called by muse, mutect2, varscan2
- SEC16A | c.3131T>C p.V1044A | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51525785; called by muse, mutect2
- SEC24B | c.2017C>T p.R673C | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1447868359, COSV54498027; called by muse, mutect2
- SEC31A | c.3113A>G p.Q1038R (on ENST00000355196 / NM_001318120.1; = p.Q999R on NM_016211.4) | Missense Mutation (SNP) | VAF 47/230 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV52344339; called by muse, mutect2, varscan2
- SEC61B | c.115T>C p.C39R | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.052); catalogued as COSV56322506; called by muse, mutect2, varscan2
- SEL1L3 | c.1258T>C p.Y420H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53539642; called by mutect2, varscan2
- SEMA3E | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV57086796; called by muse, mutect2, varscan2
- SEMA4A | c.1986G>T p.K662N | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV61772527; called by muse, mutect2, varscan2
- SERPINA11 | c.916A>G p.S306G | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.926); catalogued as COSV58241642; called by muse, mutect2, varscan2
- SERPIND1 | c.757T>G p.F253V | Missense Mutation (SNP) | VAF 54/289 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53138265; called by muse, mutect2, varscan2
- SETDB2 | c.2152del p.I718Yfs*11 | Frame Shift Del (DEL) | VAF 18/141 reads (13%) | catalogued as rs775302281, COSV57902985; called by mutect2, varscan2
- SFRP1 | c.782T>C p.L261P | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99617750; called by muse, mutect2, varscan2
- SGTB | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV66765609; called by muse, mutect2, varscan2
- SH2D4A | c.1189G>T p.D397Y | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56122207; called by muse, mutect2, varscan2
- SH3TC1 | c.2473G>A p.V825M | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.422); catalogued as rs866627114, COSV55281635; called by muse, mutect2, varscan2
- SHISA5 | c.470C>A p.A157D | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV56496788; called by mutect2, varscan2
- SIAH3 | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.956); catalogued as COSV68551663; called by muse, mutect2, varscan2
- SIN3A | c.505T>C p.S169P | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64582554; called by muse, mutect2, varscan2
- SKIL | c.1348dup p.T450Nfs*10 | Frame Shift Ins (INS) | VAF 42/266 reads (16%) | catalogued as rs1560218565; called by mutect2, pindel, varscan2
- SLC12A9 | c.1625G>A p.R542Q | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs762198192, COSV51932652; called by muse, mutect2, varscan2
- SLC13A1 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV52010302; called by muse, mutect2, varscan2
- SLC13A5 | c.676G>C p.G226R | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53422649, COSV53424679; called by muse, mutect2, varscan2
- SLC15A2 | c.1509A>T p.V503= | Splice Region (SNP) | VAF 30/254 reads (12%) | catalogued as COSV55197317; called by muse, mutect2
- SLC15A4 | c.1562A>G p.H521R | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.854); catalogued as rs1323347779, COSV57161113; called by muse, mutect2, varscan2
- SLC22A10 | c.1246G>A p.V416M | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.142); catalogued as COSV60421014; called by muse, mutect2, varscan2
- SLC22A7 | c.1421G>A p.R474Q (on ENST00000372585 / NM_153320.2; = p.R472Q on NM_006672.3) | Missense Mutation (SNP) | VAF 43/276 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.668); catalogued as rs774294045, COSV51483616; called by muse, mutect2, varscan2
- SLC24A5 | c.670A>G p.I224V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV58317101; called by muse, mutect2, varscan2
- SLC2A4RG | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs377764769; called by muse, mutect2
- SLC2A6 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs146699447; called by muse, mutect2, varscan2
- SLC2A9 | c.1002+1G>C p.X334_splice | Splice Site (SNP) | VAF 6/40 reads (15%) | catalogued as COSV53319549; called by muse, mutect2, varscan2
- SLC31A2 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 60/316 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs758999408, COSV52271885; called by muse, varscan2
- SLC32A1 | c.580T>G p.C194G | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV54146431; called by muse, mutect2, varscan2
- SLC36A3 | c.128+1G>A p.X43_splice | Splice Site (SNP) | VAF 13/54 reads (24%) | catalogued as rs776614934, COSV100077842, COSV58857907; called by muse, mutect2, varscan2
- SLC38A1 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV67063312; called by muse, mutect2, varscan2
- SLC39A11 | c.794A>G p.Y265C (on ENST00000542342 / NM_001159770.2; = p.Y258C on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1216610351, COSV55286559; called by muse, mutect2, varscan2
- SLC39A12 | c.689dup p.D231Rfs*39 | Frame Shift Ins (INS) | VAF 17/114 reads (15%) | catalogued as rs1293200115; called by mutect2, pindel, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 28/104 reads (27%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC46A3 | c.1007T>G p.M336R | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV57181538; called by muse, mutect2, varscan2
- SLC6A14 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64146782; called by muse, mutect2, varscan2
- SLC7A13 | c.372del p.S126Afs*20 | Frame Shift Del (DEL) | VAF 11/102 reads (11%) | catalogued as COSV52536834; called by mutect2, pindel, varscan2
- SLC7A14 | c.13T>G p.F5V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV51580739; called by muse, mutect2, varscan2
- SLC7A3 | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV53227156; called by muse, mutect2, varscan2
- SLC8A2 | c.658del p.S220Pfs*12 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | catalogued as rs748349403; called by mutect2, pindel, varscan2
704 further variants in this file (359 protein-altering or splice-affecting, 307 silent, 38 other) are not listed here.
